Somatic mutation profile of tumor specimen TCGA-56-8628-01A (aliquot TCGA-56-8628-01A-11D-2395-08) from TCGA case TCGA-56-8628, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 78.9 years (28,805 days).
Specimen TCGA-56-8628-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83735e43-83cf-4e35-a27d-cd8457be12d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8628-10A (Blood Derived Normal), aliquot TCGA-56-8628-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ddd5593-d776-49e3-947b-a62468c24db1

The open-access MAF lists 442 somatic variants for this specimen: 341 protein-altering or splice-affecting, 87 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 87, Nonsense Mutation 23, Frame Shift Del 18, Splice Site 9, RNA 5, 3'Flank 4, Intron 3, Splice Region 3, In Frame Del 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- ABCA4 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100933115; called by muse, mutect2, varscan2
- ABCA6 | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368916267; called by mutect2, varscan2
- ABCC11 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV100750722; called by muse, mutect2, varscan2
- ABCC12 | c.3218G>T p.C1073F | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV100252609; called by muse, mutect2, varscan2
- ABCD2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 20/150 reads (13%) | catalogued as COSV100429389, COSV99079588; called by muse, mutect2, varscan2
- ACTC1 | c.248A>T p.D83V | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV99291811; called by muse, mutect2, varscan2
- ACTRT2 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV101007601; called by muse, mutect2, varscan2
- ADAM12 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV100900375; called by muse, mutect2, varscan2
- ADAMTS18 | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV99272355; called by muse, mutect2, varscan2
- ADARB1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62344838; called by muse, mutect2, varscan2
- ADGRL3 | c.3697C>G p.R1233G (on ENST00000506720 / NM_001322402.2; = p.R1165G on NM_015236.6) | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101547065, COSV101547455, COSV72231046; called by muse, mutect2, varscan2
- AFF2 | c.2835G>A p.M945I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99663628; called by muse, mutect2, varscan2
- AGPAT1 | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100421618; called by muse, mutect2, varscan2
- AKAP3 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 42/194 reads (22%) | catalogued as COSV57414126; called by muse, mutect2, varscan2
- ALDH2 | c.220-2A>T p.X74_splice | Splice Site (SNP) | VAF 33/201 reads (16%) | catalogued as COSV99922911; called by muse, mutect2, varscan2
- ALK | c.4048C>A p.P1350T | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101201897; called by muse, mutect2, varscan2
- ANKEF1 | c.679A>G p.K227E | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.076); catalogued as COSV101001018; called by muse, mutect2, varscan2
- ANKRD35 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100841711; called by muse, mutect2, varscan2
- AOC1 | c.2226T>A p.F742L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV100710735; called by muse, mutect2, varscan2
- AP3B2 | c.3040G>C p.D1014H (on ENST00000261722; = p.D1008H on NM_004644.5) | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV99916430; called by muse, mutect2, varscan2
- APOL2 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99969112; called by muse, mutect2, varscan2
- AQP1 | c.13T>G p.F5V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV100310903; called by muse, mutect2, varscan2
- AQP9 | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs374284559; called by muse, mutect2, varscan2
- ARHGEF35 | c.1366A>T p.I456F | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.12); catalogued as COSV100967733; called by muse, mutect2, varscan2
- ARHGEF40 | c.3412C>T p.R1138W | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs759147946, COSV53881013; called by muse, mutect2, varscan2
- ARMCX2 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.207); catalogued as rs1396211532, COSV100168136; called by muse, mutect2, varscan2
- ASB5 | c.815T>A p.V272E | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV99641603; called by muse, mutect2, varscan2
- ASGR1 | c.474G>C p.W158C | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99352499; called by muse, mutect2, varscan2
- ASTN1 | c.3701G>T p.G1234V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100706490; called by muse, mutect2, varscan2
- ASTN1 | c.3700G>T p.G1234* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100706493; called by muse, mutect2, varscan2
- ATG3 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV51927264, COSV99344134; called by muse, mutect2, varscan2
- ATR | c.1863C>A p.S621R | Missense Mutation (SNP) | VAF 73/475 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100638166; called by muse, mutect2, varscan2
- BPIFB6 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV100848510; called by muse, mutect2, varscan2
- BRWD3 | c.2492G>T p.G831V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV100955968; called by muse, mutect2
- BSX | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100545228; called by muse, mutect2, varscan2
- C6orf58 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs778975580, COSV100314856; called by muse, mutect2, varscan2
- CADM2 | c.452G>A p.S151N (on ENST00000407528 / NM_001167674.2; = p.S153N on NM_153184.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101054947; called by muse, mutect2, varscan2
- CASP1 | c.854G>T p.C285F (on ENST00000436863 / NM_033292.4; = p.C264F on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100782767; called by muse, varscan2
- CCDC74B | c.1080T>G p.F360L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as COSV100134427; called by muse, mutect2, varscan2
- CCDC97 | c.911G>T p.S304I | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99523697; called by muse, mutect2, varscan2
- CD247 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.496); catalogued as COSV100758350; called by muse, mutect2, varscan2
- CDH18 | c.2284C>G p.Q762E | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.887); catalogued as COSV99931832, COSV99934322; called by muse, mutect2, varscan2
- CEP192 | c.6216C>G p.F2072L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.035); catalogued as COSV100381106; called by muse, mutect2, varscan2
- CEP89 | c.2118G>C p.Q706H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV99993400; called by muse, mutect2
- CES1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778524104, COSV100828659; called by muse, mutect2
- CHD2 | c.3319G>A p.D1107N | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as COSV101245171; called by muse, mutect2, varscan2
- CHD8 | c.5282A>G p.K1761R (on ENST00000646647 / NM_001170629.2; = p.K1482R on NM_020920.4) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.029); catalogued as COSV100765288; called by muse, mutect2, varscan2
- CHEK2 | c.898G>T p.A300S (on ENST00000382580 / NM_001005735.2; = p.A257S on NM_007194.4) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.018); catalogued as COSV100101559; called by muse, mutect2, varscan2
- CHM | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100753227; called by muse, mutect2, varscan2
- CIP2A | c.550-1G>T p.X184_splice | Splice Site (SNP) | VAF 23/86 reads (27%) | catalogued as COSV99842829; called by muse, mutect2, varscan2
- CLGN | c.535A>T p.M179L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100346587; called by muse, mutect2, varscan2
- CLRN2 | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs544368179, COSV101566456; called by muse, mutect2, varscan2
- CMAS | c.493G>T p.G165* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV57557411; called by muse, mutect2, varscan2
- CNTNAP4 | c.2694G>T p.K898N | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV100271068; called by muse, mutect2, varscan2
- COL13A1 | c.1702G>T p.G568W (on ENST00000398978 / NM_001130103.2; = p.G496W on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100637447; called by muse, mutect2, varscan2
- COL13A1 | c.1703G>T p.G568V (on ENST00000398978 / NM_001130103.2; = p.G496V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62572648; called by muse, mutect2, varscan2
- COL19A1 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506162; called by muse, mutect2, varscan2
- COL25A1 | c.1626del p.M543Wfs*67 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | catalogued as COSV67659456; called by mutect2, pindel, varscan2
- COL4A2 | c.1325C>A p.P442Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs753599916, COSV100847331; called by muse, mutect2, varscan2
- COL4A3 | c.1739C>G p.P580R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.32); catalogued as rs1486154582, COSV101170236; called by muse, mutect2, varscan2
- COL4A4 | c.4863C>A p.S1621R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306730; called by muse, mutect2, varscan2
- CRTC3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778977437, COSV51597434; called by muse, mutect2, varscan2
- CSMD3 | c.4667C>A p.P1556Q (on ENST00000297405 / NM_001363185.1; = p.P1452Q on NM_052900.3) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99832795; called by muse, mutect2, varscan2
- CTCFL | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV99712530; called by muse, mutect2, varscan2
- CTTNBP2 | c.811A>T p.R271W | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV99353783; called by muse, mutect2, varscan2
- CUL5 | c.1882G>C p.A628P | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV101263666, COSV67609807; called by muse, mutect2, varscan2
- CYBA | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs755658845, COSV99879875; called by muse, mutect2
- CYP2B6 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as COSV100137523; called by muse, mutect2, varscan2
- DAGLA | c.1868A>C p.E623A | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV99944321; called by muse, mutect2, varscan2
- DCC | c.3224T>A p.L1075Q | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.434); catalogued as COSV101472873; called by muse, mutect2, varscan2
- DDX52 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs373204877; called by muse, mutect2, varscan2
- DDX60L | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs919987077, COSV99487536; called by muse, mutect2
- DEF6 | c.197A>T p.Q66L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV100359279; called by muse, mutect2, varscan2
- DEFB112 | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100452136; called by muse, mutect2, varscan2
- DGKB | c.2402G>T p.R801L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV51765107, COSV99339050; called by muse, mutect2, varscan2
- DGKI | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55980798, COSV99934015; called by muse, mutect2, varscan2
- DGUOK | c.185A>T p.Y62F | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99903462; called by muse, mutect2, varscan2
- DMAP1 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100261682; called by muse, mutect2, varscan2
- DMXL2 | c.1126G>T p.G376C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV99196290; called by muse, mutect2, varscan2
- DNAH9 | c.1466T>C p.M489T | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99305601; called by muse, mutect2, varscan2
- DNAH9 | c.10556C>A p.P3519H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99305607; called by muse, mutect2, varscan2
- DOCK8 | c.5998A>T p.I2000F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101209905; called by muse, mutect2
- DPP6 | c.311T>C p.L104P (on ENST00000377770 / NM_001364500.2; = p.L42P on NM_001936.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100125137; called by muse, mutect2, varscan2
- DPYSL4 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs754982908, COSV100633928; called by muse, mutect2, varscan2
- DYNC1H1 | c.7937A>G p.N2646S | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV100794809; called by muse, mutect2, varscan2
- DYSF | c.3251G>T p.R1084L | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs369345918, COSV99246582; called by muse, mutect2, varscan2
- DZIP1L | c.2258G>T p.G753V | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV100551330; called by muse, mutect2, varscan2
- EFL1 | c.2531A>T p.Q844L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV99186852; called by muse, mutect2, varscan2
- EN1 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99727165; called by muse, mutect2, varscan2
- EPB42 | c.1408G>A p.E470K (on ENST00000441366 / NM_001114134.2; = p.E500K on NM_000119.3) | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs767350197, COSV100281936; called by muse, mutect2, varscan2
- EPHA5 | c.1849C>A p.L617I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.899); catalogued as COSV56675105, COSV99900678; called by muse, mutect2, varscan2
- EPHA8 | c.1645A>T p.T549S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV99384713; called by mutect2, varscan2
- EPHB1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as COSV101213115; called by muse, mutect2, varscan2
- EPHB1 | c.1499T>A p.M500K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV101213117; called by muse, mutect2, varscan2
- F5 | c.4154C>G p.S1385C | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100889075, COSV63125487; called by muse, mutect2, varscan2
- FAS | c.572A>G p.N191S (on ENST00000355740 / NM_001320619.2; = p.T219A on NM_000043.6) | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated, low confidence (0.92); catalogued as COSV100570812; called by muse, mutect2, varscan2
- FAT3 | c.12577C>T p.Q4193* | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV99965438; called by muse, mutect2, varscan2
- FBN1 | c.1955G>T p.C652F | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM023916, CM040034, CM147404, COSV100354827; called by muse, mutect2
- FCAR | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761188840, COSV100629061; called by muse, mutect2, varscan2
- FLNC | c.2819T>C p.M940T | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100368006; called by muse, mutect2, varscan2
- FOXK1 | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100195059; called by muse, mutect2, varscan2
- FSCB | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100469257; called by muse, mutect2, varscan2
- FSCB | c.1040T>G p.L347R | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.206); catalogued as rs138197025; called by muse, mutect2, varscan2
- GAS2L2 | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.125); catalogued as rs1555598854; called by muse, mutect2, varscan2
- GLB1L2 | c.647A>G p.K216R | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as rs925116255, COSV100335309; called by muse, mutect2, varscan2
- GRM6 | c.1393G>T p.D465Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51449672, COSV99179585; called by muse, mutect2, varscan2
- GTF2H4 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.065); catalogued as COSV99461743; called by muse, mutect2, varscan2
- H4C4 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs759432453, COSV100534412; called by muse, mutect2, varscan2
- HAUS3 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99704252; called by muse, mutect2, varscan2
- HAVCR1 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV100208200, COSV100208612; called by muse, varscan2
- HDLBP | c.944G>A p.G315D | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV100190434; called by muse, mutect2, varscan2
- HECW2 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99646961; called by muse, mutect2, varscan2
- HEPACAM2 | c.185C>T p.S62L (on ENST00000394468 / NM_001039372.4; = p.S50L on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as COSV100506529; called by muse, mutect2, varscan2
- HHIPL2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596780; called by muse, mutect2, varscan2
- HHIPL2 | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV100596810; called by muse, mutect2, varscan2
- HOXA6 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99762240; called by muse, mutect2, varscan2
- HSPG2 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as rs374140235; called by muse, mutect2, varscan2
- HYDIN | c.8105C>G p.A2702G | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.08); catalogued as COSV99047265, COSV99992727; called by muse, varscan2
- IFNL1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100373636; called by muse, mutect2, varscan2
- IGF2BP2 | c.1759C>G p.Q587E | Missense Mutation (SNP) | VAF 25/357 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV100649064; called by muse, mutect2
- IGHG3 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs764898311; called by muse, mutect2, varscan2
- IL17F | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV100277189; called by muse, mutect2, varscan2
- IL26 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1423177764, COSV99970883, COSV99970969; called by muse, mutect2
- INO80D | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV101305815; called by muse, mutect2
- IPCEF1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99499601; called by muse, mutect2, varscan2
- ITGAD | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101210442; called by muse, mutect2, varscan2
- ITK | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV101439701; called by muse, mutect2, varscan2
- ITPKC | c.1257G>T p.G419= | Splice Region (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99648703; called by muse, mutect2
- KCNA3 | c.1599A>T p.E533D | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV100871251; called by muse, mutect2, varscan2
- KCNC2 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100128716; called by muse, varscan2
- KIF5A | c.2695C>A p.R899S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99672885, COSV99673698; called by muse, mutect2
- KIRREL3 | c.917C>A p.T306K | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV101585704; called by muse, mutect2, varscan2
- KLHL4 | c.594G>T p.L198F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100909501; called by muse, mutect2, varscan2
- KMT2B | c.2070G>T p.E690D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.525); catalogued as COSV99386032; called by muse, mutect2, varscan2
- KRTAP10-4 | c.828C>A p.C276* | Nonsense Mutation (SNP) | VAF 53/251 reads (21%) | catalogued as COSV100551260; called by muse, mutect2, varscan2
- LENG8 | c.2090C>G p.A697G | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV100418046; called by muse, mutect2, varscan2
- LILRA4 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as rs560878491, COSV52492220, COSV52496130; called by muse, mutect2, varscan2
- LPA | c.3290G>T p.G1097V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1419730183, COSV100306830; called by muse, mutect2, varscan2
- LRP1B | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV101253032, COSV67233618; called by muse, mutect2, varscan2
- LRP2 | c.1966C>G p.Q656E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99788119; called by muse, mutect2, varscan2
- LRRC55 | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.192); catalogued as COSV101546735; called by muse, mutect2, varscan2
- LTN1 | c.3215G>C p.G1072A | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100797970; called by muse, mutect2, varscan2
- LVRN | c.1262G>C p.W421S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100773376, COSV100773416; called by muse, mutect2, varscan2
- MAGEE1 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV100819380; called by muse, mutect2, varscan2
- MAK16 | c.176-2A>G p.X59_splice | Splice Site (SNP) | VAF 49/104 reads (47%) | catalogued as COSV100789439; called by muse, mutect2, varscan2
- MAN2C1 | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99145363; called by muse, mutect2
- MAP4K3 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99810324; called by muse, mutect2, varscan2
- MATK | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV100036040; called by muse, mutect2, varscan2
- MED12 | c.2587A>T p.M863L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100377733; called by muse, mutect2, varscan2
- MEGF11 | c.1654T>G p.C552G | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.334); catalogued as COSV99987628; called by muse, mutect2, varscan2
- MIA3 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100719418; called by muse, mutect2, varscan2
- MINDY3 | c.1116+1G>T p.X372_splice | Splice Site (SNP) | VAF 26/151 reads (17%) | catalogued as COSV99510710; called by muse, mutect2, varscan2
- MKRN3 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.916); catalogued as COSV100091085, COSV58808479; called by muse, varscan2
- MORC1 | c.224-1G>A p.X75_splice | Splice Site (SNP) | VAF 36/147 reads (24%) | catalogued as COSV51716353; called by muse, mutect2, varscan2
- MS4A5 | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.025); catalogued as COSV100280986; called by muse, mutect2, varscan2
- MT1H | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100189978, COSV60090439; called by muse, mutect2, varscan2
- MTURN | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as COSV100188762; called by muse, mutect2, varscan2
- MYF5 | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV57354370, COSV99953253; called by muse, mutect2, varscan2
- MYO15A | c.9081C>T p.P3027= | Splice Region (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99232468; called by muse, mutect2, varscan2
- MYO16 | c.3857G>C p.S1286T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100696654; called by muse, mutect2, varscan2
- NAIP | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV99519267; called by muse, mutect2, varscan2
- NAV3 | c.3848C>A p.A1283E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99890165; called by muse, mutect2, varscan2
- NBAS | c.7024G>T p.E2342* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99869190; called by muse, mutect2, varscan2
- NCAM1 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV100377593, COSV57522720; called by muse, mutect2, varscan2
- NCAM2 | c.1823G>A p.S608N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.352); catalogued as COSV53109082, COSV99522782; called by muse, mutect2, varscan2
- NCAM2 | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53063373, COSV99522784, COSV99525705; called by muse, mutect2, varscan2
- NCKAP5L | c.3457G>T p.D1153Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100258704; called by muse, mutect2, varscan2
- NCLN | c.1594A>G p.I532V | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99859878; called by muse, mutect2, varscan2
- NCOA6 | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100749985; called by muse, mutect2, varscan2
- NDC80 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99859599; called by muse, mutect2, varscan2
- NES | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV100957853; called by muse, mutect2, varscan2
- NFIA | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100963727, COSV64545363; called by muse, mutect2, varscan2
- NLRP13 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61622761; called by muse, mutect2, varscan2
- NOD2 | c.1675G>T p.G559C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV100318503; called by muse, mutect2, varscan2
- NPY5R | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV100642757; called by muse, mutect2, varscan2
- NSUN2 | c.1703G>C p.R568P | Missense Mutation (SNP) | VAF 25/272 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52955203, COSV99243130; called by muse, mutect2
- NTNG1 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.715); catalogued as COSV53992703, COSV99636991; called by muse, mutect2, varscan2
- NUP62 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 34/196 reads (17%) | catalogued as COSV100351989, COSV61311455; called by muse, mutect2, varscan2
- NXPE1 | c.1405C>G p.P469A (on ENST00000424269; = p.P327A on NM_152315.5) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52628325, COSV99321031; called by muse, mutect2, varscan2
- OR11G2 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as rs1338958351, COSV100639948; called by muse, mutect2, varscan2
- OR11G2 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100639950; called by muse, mutect2, varscan2
- OR11H4 | c.664A>T p.M222L | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100197495; called by muse, mutect2, varscan2
- OR13C9 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99403421; called by muse, mutect2, varscan2
- OR1L1 | c.613C>T p.H205Y (on ENST00000373686; = p.H155Y on NM_001005236.3) | Missense Mutation (SNP) | VAF 86/351 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1450906395, COSV100542129; called by muse, mutect2, varscan2
- OR2AG2 | c.742G>T p.V248F | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58455089; called by muse, mutect2
- OR2T3 | c.849C>A p.Y283* | Nonsense Mutation (SNP) | VAF 42/329 reads (13%) | catalogued as COSV100613205; called by muse, mutect2, varscan2
- OR4C12 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as rs201564751, COSV58860586; called by muse, mutect2, varscan2
- OR4D10 | c.117G>C p.L39F | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs746612717, COSV101597010; called by muse, mutect2, varscan2
- OR4M1 | c.315C>G p.H105Q | Missense Mutation (SNP) | VAF 72/632 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100271163; called by muse, mutect2, varscan2
- OR4P4 | c.100A>T p.I34F | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.563); catalogued as COSV58922356; called by muse, mutect2, varscan2
- OR4S1 | c.245A>T p.D82V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100180236; called by muse, mutect2, varscan2
- OR6C2 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as COSV100498687, COSV59516119; called by muse, mutect2, varscan2
- OR6N1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100625152; called by muse, mutect2, varscan2
- OR7D4 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100432708, COSV58072546; called by muse, mutect2, varscan2
- OR7G2 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100560426; called by muse, mutect2, varscan2
- OR8B4 | c.142T>A p.L48I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.163); catalogued as COSV100635810; called by muse, mutect2, varscan2
- OR9Q2 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285415; called by muse, mutect2, varscan2
- OSGEP | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99247977; called by muse, mutect2, varscan2
- PARD3 | c.3863G>C p.R1288P | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100631864; called by muse, mutect2, varscan2
- PARP14 | c.2389G>T p.V797F | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV101506268; called by muse, mutect2, varscan2
- PATJ | c.384G>T p.Q128H | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV100334043; called by muse, mutect2, varscan2
- PCDHA10 | c.1417A>T p.I473F | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV56489223; called by muse, mutect2, varscan2
- PCDHGB1 | c.2321A>T p.Q774L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99536981; called by muse, mutect2, varscan2
- PCGF1 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99283289; called by muse, mutect2, varscan2
- PCLO | c.11992G>T p.A3998S | Missense Mutation (SNP) | VAF 95/459 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.187); catalogued as rs780418136, COSV100431708; called by muse, mutect2, varscan2
- PDCD4 | c.778-1G>T p.X260_splice | Splice Site (SNP) | VAF 29/139 reads (21%) | catalogued as rs1445530040, COSV99700937; called by muse, mutect2, varscan2
- PDE4A | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs1225545987, COSV100764097; called by muse, mutect2, varscan2
- PDE9A | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs746415649, COSV99371478; called by muse, mutect2
- PDE9A | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99371483; called by muse, mutect2
- PDGFB | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.09); catalogued as rs779333096, COSV100483451; called by muse, mutect2, varscan2
- PEAK1 | c.4643C>T p.P1548L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as COSV56942720; called by muse, mutect2, varscan2
- PHACTR2 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99991464; called by muse, mutect2, varscan2
- PIK3CB | c.2442G>T p.M814I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100005570; called by muse, mutect2, varscan2
- PKD1 | c.2366G>T p.G789V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99237992; called by muse, mutect2
- PKHD1L1 | c.4875G>T p.M1625I | Missense Mutation (SNP) | VAF 105/367 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV101006030; called by muse, mutect2, varscan2
- PKHD1L1 | c.6906G>T p.L2302F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101006031; called by muse, mutect2, varscan2
- PLA2G4D | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); catalogued as COSV99299634; called by muse, mutect2, varscan2
- PLPPR5 | c.135C>G p.C45W | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99587241; called by muse, mutect2, varscan2
- PMFBP1 | c.1068C>A p.D356E | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99400755; called by muse, mutect2, varscan2
- PNLIP | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV100981783; called by muse, mutect2, varscan2
- POLD2 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV104384741, COSV56258910; called by muse, mutect2, varscan2
- POTEE | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as rs537365923, COSV100387315, COSV100387770; called by muse, mutect2, varscan2
- PRELP | c.982G>T p.G328* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100557816; called by muse, mutect2, varscan2
- PRKCG | c.1368del p.H456Qfs*26 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | catalogued as COSV54731227; called by mutect2, pindel, varscan2
- PRPF6 | c.1724G>T p.S575I | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99411916; called by muse, mutect2, varscan2
- PRSS21 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.337); catalogued as rs761289786, COSV99135523; called by muse, mutect2, varscan2
- PSG8 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 105/742 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747139040, COSV100126145; called by muse, mutect2, varscan2
- PTPN22 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100703593; called by muse, mutect2, varscan2
- PTPRB | c.5150A>G p.Q1717R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV99717190; called by muse, mutect2, varscan2
- QSOX2 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100699753; called by muse, mutect2, varscan2
- QSOX2 | c.1459G>T p.A487S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100699756; called by muse, mutect2, varscan2
- RAMP3 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV99642257; called by muse, mutect2, varscan2
- RECQL | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100131253; called by muse, mutect2
- RGS4 | c.232del p.A78Lfs*3 | Frame Shift Del (DEL) | VAF 20/148 reads (14%) | catalogued as COSV63356976; called by mutect2, pindel, varscan2
- RND1 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV100552144; called by muse, mutect2, varscan2
- RTL3 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV100329743, COSV58184605; called by muse, mutect2, varscan2
- RTTN | c.4864G>A p.D1622N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as rs886042189, COSV99732155; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.5914C>G p.Q1972E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100769820; called by muse, mutect2
- RYR3 | c.9874C>G p.R3292G (on ENST00000389232; = p.R3293G on NM_001036.6) | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV101212643; called by muse, mutect2, varscan2
- SALL1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs201220768, COSV51753393, COSV99175093; called by muse, mutect2, varscan2
- SAMD3 | c.659T>C p.L220S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.077); catalogued as rs750368407, COSV100931756; called by muse, mutect2, varscan2
- SELL | c.522G>T p.Q174H (on ENST00000650983; = p.Q161H on NM_000655.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1158888379, COSV99357528; called by muse, mutect2, varscan2
- SELP | c.1795C>A p.H599N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99739724; called by muse, mutect2, varscan2
- SERPINA5 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100291594; called by muse, mutect2, varscan2
- SERPINF2 | c.1394G>C p.R465P | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100131923; called by muse, mutect2, varscan2
- SEZ6L2 | c.1369G>T p.E457* (on ENST00000308713 / NM_001114099.3; = p.E387* on NM_012410.4) | Nonsense Mutation (SNP) | VAF 26/113 reads (23%) | catalogued as COSV100435369; called by muse, mutect2, varscan2
- SHOX | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV100479025; called by muse, mutect2, varscan2
- SIRPG | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99403711; called by muse, mutect2, varscan2
- SIRT5 | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100702807; called by muse, mutect2, varscan2
- SLC17A2 | c.537C>G p.S179R | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99614278; called by muse, mutect2, varscan2
- SLC2A13 | c.1619C>A p.A540E | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV55122296; called by muse, mutect2, varscan2
- SLC30A9 | c.1241C>A p.T414N | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100048175; called by muse, mutect2, varscan2
- SLC35F4 | c.632del p.P211Qfs*8 (on ENST00000339762 / NM_001352015.2; = p.P175Qfs*8 on NM_001206920.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as COSV60262653; called by mutect2, pindel, varscan2
- SLC44A5 | c.1738T>C p.Y580H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as rs1420504834, COSV100901882; called by muse, mutect2, varscan2
- SLC5A4 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56671106, COSV99831886; called by muse, mutect2, varscan2
- SLCO1A2 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as COSV100261798; called by muse, mutect2, varscan2
- SLX4IP | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV100570455; called by muse, mutect2, varscan2
- SMARCAL1 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs145685056; called by muse, mutect2, varscan2
- SMG8 | c.1323A>T p.E441D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV99958798; called by muse, mutect2, varscan2
- SNRPN | c.723G>T p.*241Yext*17 | Nonstop Mutation (SNP) | VAF 50/249 reads (20%) | catalogued as COSV100578168; called by muse, mutect2, varscan2
- SNTG1 | c.1251C>A p.S417R | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV99383356; called by muse, mutect2, varscan2
- SNX29 | c.1899G>T p.P633= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as rs200955496, COSV100028397, COSV60063873; called by muse, mutect2, varscan2
- SPAG16 | c.833-2A>G p.X278_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as rs777161931, COSV99793670, COSV99793709; called by muse, varscan2
- SPAG17 | c.2704T>C p.S902P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100308894; called by muse, mutect2, varscan2
- SPHKAP | c.3024C>G p.D1008E | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.662); catalogued as rs200492792, COSV100764082; called by muse, mutect2, varscan2
- STIM2 | c.1228G>C p.D410H | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99402538; called by muse, mutect2, varscan2
- STK36 | c.1569G>C p.W523C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99831291; called by muse, mutect2
- SYNE1 | c.14301A>T p.E4767D (on ENST00000367255 / NM_182961.4; = p.E4696D on NM_033071.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV99562165; called by muse, mutect2, varscan2
- SYNE1 | c.12190C>A p.Q4064K (on ENST00000367255 / NM_182961.4; = p.Q3993K on NM_033071.3) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99562169; called by muse, mutect2
- SYNE1 | c.10747C>A p.Q3583K (on ENST00000367255 / NM_182961.4; = p.Q3590K on NM_033071.3) | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV99562177; called by muse, mutect2, varscan2
- SYT4 | c.34+1G>T p.X12_splice | Splice Site (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99673733; called by muse, varscan2
- TAAR5 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57799641, COSV99236884; called by muse, mutect2, varscan2
- TAFA2 | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101353249; called by muse, mutect2, varscan2
- TBL2 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.221); catalogued as COSV59786556; called by muse, mutect2, varscan2
- TCP11 | c.481A>C p.K161Q (on ENST00000512012; = p.K99Q on NM_018679.5) | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV99774271; called by muse, mutect2, varscan2
- TDP1 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.371); catalogued as COSV100187762; called by muse, mutect2, varscan2
- TDP1 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV100187763; called by muse, mutect2, varscan2
- TDRD5 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV99676132; called by muse, mutect2, varscan2
- TENM1 | c.5310G>T p.E1770D | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100949844; called by muse, mutect2, varscan2
- TGM2 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100821599; called by muse, mutect2, varscan2
- THSD7B | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55649012, COSV99749592; called by muse, mutect2, varscan2
- THSD7B | c.3342A>T p.E1114D (on ENST00000272643; = p.E1112D on NM_001316349.2) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99749597; called by muse, mutect2, varscan2
- TIMELESS | c.3040+1G>T p.X1014_splice | Splice Site (SNP) | VAF 26/146 reads (18%) | catalogued as COSV99973932; called by muse, mutect2, varscan2
- TLL2 | c.2757T>A p.C919* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100780257; called by muse, mutect2, varscan2
- TLL2 | c.2756G>A p.C919Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100780258; called by muse, mutect2, varscan2
- TM4SF4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV100541853; called by muse, mutect2, varscan2
- TMC2 | c.1047C>A p.F349L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV100727559, COSV62653969; called by muse, mutect2, varscan2
- TMEM202 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs143076809; called by muse, mutect2, varscan2
- TMPRSS15 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99517743; called by muse, mutect2, varscan2
- TNNI3 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV100787927; called by muse, mutect2, varscan2
- TRABD2A | c.884A>G p.Y295C (on ENST00000409520 / NM_001277053.2; = p.Y246C on NM_001080824.3) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100119859; called by muse, mutect2, varscan2
- TTN | c.63598C>A p.P21200T (on ENST00000591111; = p.P13776T on NM_003319.4) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | PolyPhen probably damaging (0.964); catalogued as COSV100610294; called by muse, mutect2, varscan2
- TTN | c.56147C>A p.S18716Y (on ENST00000591111; = p.S11292Y on NM_003319.4) | Missense Mutation (SNP) | VAF 25/138 reads (18%) | PolyPhen probably damaging (0.998); catalogued as COSV100610300; called by muse, mutect2, varscan2
- TTN | c.14875G>T p.D4959Y (on ENST00000591111; = p.D4032Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/237 reads (19%) | PolyPhen probably damaging (0.961); catalogued as COSV59917690, COSV59950354; called by muse, mutect2, varscan2
- UBE2U | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100934380; called by muse, mutect2, varscan2
- UNC13B | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.011); catalogued as COSV101036614; called by muse, mutect2, varscan2
- UROD | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99870151; called by muse, mutect2, varscan2
- USH2A | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV100233672; called by muse, mutect2
- VARS1 | c.1991A>G p.N664S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100791802; called by muse, mutect2, varscan2
- VIPR1 | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100285611; called by muse, mutect2, varscan2
- VPS13B | c.1340T>C p.I447T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100661839; called by muse, mutect2, varscan2
- VPS39 | c.1612A>T p.R538W (on ENST00000348544 / NM_001301138.2; = p.R527W on NM_015289.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100529147; called by muse, mutect2, varscan2
- VWA3A | c.2768T>C p.M923T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs369406647; called by muse, mutect2, varscan2
- VWA5A | c.2074G>T p.G692C | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827851; called by muse, mutect2, varscan2
- WDR17 | c.3800C>T p.P1267L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99707494; called by muse, mutect2, varscan2
- WDR72 | c.3000C>A p.H1000Q | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as COSV100854406; called by muse, mutect2, varscan2
- WWC3 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV101081398; called by muse, varscan2
- YAE1 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs767147083, COSV56233473; called by muse, mutect2, varscan2
- ZEB1 | c.2953T>A p.Y985N | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100314286; called by muse, mutect2, varscan2
- ZFHX4 | c.6790A>G p.N2264D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV99262022; called by muse, mutect2, varscan2
- ZFHX4 | c.9827C>A p.P3276H | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99262030; called by muse, mutect2, varscan2
- ZHX1 | c.2074A>G p.K692E | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV99933620; called by muse, mutect2, varscan2
- ZIC4 | c.617G>T p.C206F | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101267947; called by muse, mutect2, varscan2
- ZNF329 | c.632G>T p.C211F | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100798725; called by muse, mutect2, varscan2
- ZNF493 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs913022582, COSV62750853; called by muse, mutect2, varscan2
- ZNF567 | c.1516G>A p.E506K (on ENST00000536254 / NM_001322913.1; = p.E475K on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100658771, COSV99054019; called by muse, mutect2, varscan2
- ZNF781 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as COSV62200419, COSV62201378; called by muse, mutect2, varscan2
- AKAP6 | c.16del p.V6* | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- ASB5 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2
- ASXL3 | c.266del p.P89Qfs*8 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- ATP13A1 | c.3514G>C p.V1172L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2
- CRYBG3 | c.6695_6697del p.S2232del | In Frame Del (DEL) | VAF 11/84 reads (13%) | called by pindel, varscan2
- DACT1 | c.2460del p.K821Rfs*10 | Frame Shift Del (DEL) | VAF 25/155 reads (16%) | called by mutect2, pindel, varscan2
- FARP1 | c.330del p.H110Qfs*8 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- GOLGA6L22 | c.131del p.G44Afs*29 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.1246_1259del p.F416Rfs*49 | Frame Shift Del (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- IGHV4-59 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- MTX1 | c.31C>A p.R11S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.106); called by muse, mutect2
- OR14A16 | c.202del p.D68Ifs*17 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel*, varscan2
- OR8D4 | c.698del p.G233Afs*13 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | called by mutect2, pindel, varscan2
- PAK6 | c.555_578del p.F185_C192del | In Frame Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- SLC32A1 | c.317del p.G106Afs*20 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- SLC6A12 | c.1688dup p.P564Sfs*13 | Frame Shift Ins (INS) | VAF 13/93 reads (14%) | called by mutect2, pindel, varscan2
- SOX1 | c.370del p.R124Afs*82 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- TIAM2 | c.542del p.G181Afs*18 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- TMEM62 | c.1225_1226del p.V409Sfs*4 | Frame Shift Del (DEL) | VAF 16/124 reads (13%) | called by mutect2, pindel, varscan2
- TNNT1 | c.540G>T p.E180D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- TRPM8 | c.1080_1098del p.F361Pfs*25 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel
- VNN2 | c.1038del p.F346Lfs*24 | Frame Shift Del (DEL) | VAF 30/167 reads (18%) | called by mutect2, pindel, varscan2
- ZNF488 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCD4 | c.244C>T p.L82= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100083921, COSV100084237; called by muse, mutect2, varscan2
- ADAMTS9 | c.5601C>T p.A1867= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV55793165, COSV99899298; called by muse, mutect2, varscan2
- ADGRF4 | c.1299G>T p.T433= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as COSV99348323; called by muse, mutect2, varscan2
- ALB | c.1131T>C p.Y377= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs145924167; called by muse, mutect2, varscan2
- ANKRD55 | c.1599A>T p.P533= | Silent (SNP) | VAF 43/222 reads (19%) | catalogued as COSV100591256; called by muse, mutect2, varscan2
- BARHL2 | c.594G>T p.R198= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100966052, COSV64981386; called by muse, mutect2, varscan2
- BOD1L1 | c.4086C>T p.S1362= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as COSV99239224; called by muse, mutect2, varscan2
- BSG | c.547C>T p.L183= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100344736; called by muse, mutect2, varscan2
- C6orf58 | c.981A>C p.G327= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100314859; called by muse, mutect2, varscan2
- CADM2 | c.1284A>G p.E428= (on ENST00000407528 / NM_001167674.2; = p.E430= on NM_153184.4) | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV101054950; called by muse, mutect2, varscan2
- CARMIL3 | c.705G>T p.V235= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV100549551; called by muse, mutect2, varscan2
- CASS4 | c.1836C>T p.I612= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100824662; called by muse, mutect2, varscan2
- CLCA2 | c.999A>G p.Q333= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100991507; called by muse, mutect2, varscan2
- CLCN3 | c.1569A>T p.P523= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100641684; called by muse, mutect2, varscan2
- CP | c.15A>T p.I5= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99224046; called by muse, mutect2, varscan2
- CSMD1 | c.7167A>G p.L2389= (on ENST00000520002; = p.L2388= on NM_033225.6) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs752415477, COSV100147057; called by muse, mutect2, varscan2
- CSMD3 | c.276A>T p.T92= | Silent (SNP) | VAF 60/208 reads (29%) | catalogued as COSV99832800; called by muse, mutect2, varscan2
- DCAF4L2 | c.990G>T p.A330= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV100150825; called by muse, mutect2, varscan2
- DLEC1 | c.1401C>T p.P467= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs775463951, COSV100342109; called by muse, mutect2, varscan2
- DMD | c.3906C>A p.I1302= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV63747860; called by muse, mutect2, varscan2
- EFCC1 | c.1482G>A p.E494= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV101459987; called by muse, mutect2, varscan2
- FBN1 | c.1953G>T p.V651= | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as COSV100354828; called by muse, mutect2
- FSD2 | c.2238C>A p.V746= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV100575116; called by muse, mutect2
- FSTL5 | c.2307G>T p.V769= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as COSV100054788; called by muse, mutect2, varscan2
- GALR1 | c.300C>G p.T100= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as COSV100231797; called by muse, mutect2, varscan2
- GIPC2 | c.573T>C p.F191= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as COSV100803667; called by muse, mutect2, varscan2
- GPBP1 | c.852G>A p.Q284= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV99302720; called by muse, mutect2, varscan2
- GPR63 | c.228A>G p.L76= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV100013302; called by muse, mutect2, varscan2
- GREB1 | c.4179C>A p.L1393= | Silent (SNP) | VAF 44/276 reads (16%) | catalogued as COSV99302833; called by muse, mutect2, varscan2
- GRM3 | c.1578C>G p.V526= | Silent (SNP) | VAF 31/174 reads (18%) | catalogued as COSV100862502; called by muse, mutect2, varscan2
- H2AC13 | c.166C>T p.L56= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100704364; called by muse, mutect2, varscan2
- HDHD5 | c.465C>A p.V155= (on ENST00000336737 / NM_033070.3; = p.V125= on NM_017829.5) | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99324735; called by muse, mutect2, varscan2
- HFM1 | c.2667C>G p.S889= | Silent (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2
- IGHM | c.870C>A p.I290= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.282T>A p.T94= | Silent (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- IKBIP | c.399C>T p.S133= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs761086372, COSV100689773, COSV61082065; called by muse, mutect2, varscan2
- IL2 | c.18C>A p.L6= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV56986731; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.309C>A p.G103= | Silent (SNP) | VAF 28/201 reads (14%) | catalogued as COSV99860753; called by muse, mutect2, varscan2
- ITGAD | c.1579T>C p.L527= | Silent (SNP) | VAF 51/224 reads (23%) | catalogued as rs756389916, COSV101210443; called by muse, mutect2, varscan2
- KCNC2 | c.963G>T p.V321= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV54370399; called by muse, varscan2
- KCNC2 | c.834G>A p.T278= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as rs1033220922, COSV100128720; called by muse, varscan2
- KRTAP9-3 | c.471T>C p.S157= | Silent (SNP) | VAF 56/231 reads (24%) | catalogued as COSV101370149; called by muse, mutect2, varscan2
- LBP | c.894T>C p.Y298= | Silent (SNP) | VAF 35/179 reads (20%) | catalogued as COSV99460816; called by muse, mutect2, varscan2
- LRRC4C | c.144T>A p.P48= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99538017; called by muse, mutect2, varscan2
- LTBP4 | c.4260C>G p.L1420= (on ENST00000308370 / NM_001042544.1; = p.L1383= on NM_003573.2) | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99191084; called by muse, mutect2, varscan2
- LVRN | c.48C>A p.A16= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100773415; called by muse, mutect2
- LYST | c.3165A>T p.L1055= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV101089208; called by muse, mutect2, varscan2
- MAP10 | c.1368G>T p.P456= | Silent (SNP) | VAF 46/177 reads (26%) | catalogued as rs368167890, COSV69364073; called by muse, mutect2, varscan2
- MCM10 | c.78A>T p.S26= | Silent (SNP) | VAF 62/197 reads (31%) | catalogued as COSV101098085; called by muse, mutect2, varscan2
- MCM10 | c.600C>T p.P200= (on ENST00000484800 / NM_182751.3; = p.P199= on NM_018518.5) | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV101098087; called by muse, mutect2, varscan2
- MOGAT2 | c.552T>A p.I184= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99549519; called by muse, mutect2, varscan2
- MS4A6A | c.390G>A p.V130= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100124791; called by muse, mutect2, varscan2
- MTNR1B | c.153C>A p.T51= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV57065904, COSV99925094; called by muse, mutect2, varscan2
- MUC2 | c.651C>A p.S217= | Silent (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- MUC5AC | c.14232C>T p.T4744= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV100611426; called by muse, mutect2, varscan2
- MYF6 | c.483G>T p.G161= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV99952774; called by muse, mutect2
- MYH15 | c.4962C>A p.S1654= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as COSV99843097; called by muse, mutect2, varscan2
- MYH15 | c.3645C>A p.L1215= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as COSV99843099, COSV99844460; called by muse, mutect2, varscan2
- MYLK2 | c.732C>A p.L244= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as COSV101044760; called by muse, mutect2, varscan2
- MYO7B | c.771C>T p.C257= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV67349597; called by muse, mutect2, varscan2
- NAALAD2 | c.120T>A p.S40= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV100428391; called by muse, mutect2, varscan2
- NLRP5 | c.1503G>A p.L501= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV101173623; called by muse, mutect2, varscan2
- OLFM3 | c.1212G>A p.L404= (on ENST00000338858 / NM_001288821.1; = p.L384= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/205 reads (17%) | catalogued as COSV100129367; called by muse, mutect2, varscan2
- OR4K14 | c.747G>C p.T249= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs539150551, COSV100520400, COSV59292074; called by muse, mutect2, varscan2
- OR4K2 | c.420G>T p.V140= | Silent (SNP) | VAF 52/469 reads (11%) | catalogued as COSV100064409; called by muse, mutect2, varscan2
- OR5AS1 | c.69C>A p.L23= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV57982869; called by muse, mutect2, varscan2
- OR6X1 | c.177C>T p.F59= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV100020523, COSV60010716; called by muse, mutect2, varscan2
- PDZRN3 | c.1068G>T p.T356= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- PKHD1 | c.5976T>C p.D1992= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs371017079; called by muse, mutect2, varscan2
- PRAMEF14 | c.120C>T p.F40= | Silent (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2, varscan2
- PRKDC | c.10554G>T p.V3518= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100040270; called by muse, mutect2, varscan2
- RIPOR2 | c.1326C>T p.A442= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99429058; called by muse, mutect2, varscan2
- RTN4RL2 | c.39C>T p.A13= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as COSV100625450; called by muse, mutect2, varscan2
- RYR3 | c.1876C>A p.R626= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV66780293, COSV66811073; called by muse, mutect2, varscan2
- SCN7A | c.1710C>T p.N570= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101313193, COSV69270907; called by muse, mutect2
- SLC17A3 | c.945T>C p.Y315= | Silent (SNP) | VAF 27/122 reads (22%) | catalogued as rs892286799, COSV100399184; called by muse, mutect2, varscan2
- SMARCAL1 | c.2031G>T p.L677= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100619866; called by muse, mutect2, varscan2
- SPTB | c.1114C>A p.R372= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV101072098; called by muse, mutect2, varscan2
- SRPX | c.148A>C p.R50= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100656040; called by muse, mutect2, varscan2
- SYNE2 | c.12852A>G p.T4284= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV100647492; called by muse, mutect2, varscan2
- TCF20 | c.5778G>A p.S1926= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1378115635; called by muse, mutect2, varscan2
- TCN1 | c.1053T>A p.T351= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV99953229, COSV99953353; called by muse, mutect2, varscan2
- TNS1 | c.1506C>T p.D502= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as rs368231680; called by muse, mutect2, varscan2
- TRIM42 | c.1962A>G p.G654= | Silent (SNP) | VAF 26/207 reads (13%) | catalogued as COSV99648314; called by muse, mutect2, varscan2
- TTN | c.10824G>T p.V3608= (on ENST00000591111; = p.V3562= on NM_003319.4) | Silent (SNP) | VAF 37/249 reads (15%) | catalogued as COSV100610303; called by muse, mutect2, varscan2
- URI1 | c.1518A>G p.P506= | Silent (SNP) | VAF 48/257 reads (19%) | catalogued as COSV100368979; called by muse, mutect2, varscan2
- ZFHX4 | c.8688C>A p.A2896= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99262025; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52098564 G>T | 3'Flank (SNP) | VAF 22/123 reads (18%) | catalogued as COSV100801456; called by muse, mutect2, varscan2
- BTN2A3P | n.1727A>G | RNA (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- CGREF1 | c.718+10G>A | Intron (SNP) | VAF 48/396 reads (12%) | catalogued as rs1057389, COSV99565328; called by muse, varscan2
- DENND10P1 | n.633G>T | RNA (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.199A>G | RNA (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- MC3R | c.-101A>G | 5'UTR (SNP) | VAF 48/228 reads (21%) | catalogued as rs774291461, COSV99710566; called by muse, mutect2
- MGAM | c.4618+1201A>G | Intron (SNP) | VAF 33/186 reads (18%) | catalogued as COSV101527466; called by muse, mutect2, varscan2
- MIR513A1 | n.70T>C | RNA (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099767 A>G | 5'Flank (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- OR52A4P | chr11:5120764 A>G | 3'Flank (SNP) | VAF 22/106 reads (21%) | called by muse, mutect2, varscan2
- OR52A4P | n.638G>T | RNA (SNP) | VAF 31/128 reads (24%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948520 C>G | 3'Flank (SNP) | VAF 29/144 reads (20%) | catalogued as COSV99988189; called by muse, mutect2, varscan2
- TAOK2 | chr16:29990937 G>T | 3'Flank (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99663004; called by muse, mutect2, varscan2
- TTN | c.34264+2933G>T | Intron (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100610301; called by muse, mutect2
